Somatic mutation profile of tumor specimen TCGA-CM-4748-01A (aliquot TCGA-CM-4748-01A-01D-1408-10) from TCGA case TCGA-CM-4748, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 53.4 years (19,509 days).
Specimen TCGA-CM-4748-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f68267f-6156-4ff0-84d3-f52291cb3e4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-4748-10A (Blood Derived Normal), aliquot TCGA-CM-4748-10A-01D-1408-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c92615ea-b10d-41f3-bbfd-913867f0ea03

The open-access MAF lists 70 somatic variants for this specimen: 51 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 18, Nonsense Mutation 5, Frame Shift Del 2, In Frame Del 1, Splice Site 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 31/93 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 62/157 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- SLC2A1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs139412383, CM1513759; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTRT1 | c.620T>C p.L207P | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.073); catalogued as COSV100947571; called by mutect2, varscan2
- ADGRA2 | c.2089G>A p.V697I | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs377569553; called by muse, mutect2, varscan2
- ADHFE1 | c.112C>G p.P38A | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV52555951; called by muse, mutect2, varscan2
- ALOXE3 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV59076054; called by muse, mutect2, varscan2
- APBA2 | c.1595G>A p.G532D | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV67104756; called by muse, mutect2, varscan2
- APBB1 | c.1447C>T p.R483C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs184224900, COSV54975089; called by muse, mutect2, varscan2
- BCOR | c.377del p.P126Rfs*35 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as COSV60704978; called by mutect2, pindel
- C8B | c.509G>A p.W170* | Nonsense Mutation (SNP) | VAF 45/123 reads (37%) | catalogued as COSV64778014; called by muse, mutect2, varscan2
- CELSR2 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as rs761111571, COSV54767033, COSV54773438; called by muse, mutect2, varscan2
- CP | c.1448A>G p.N483S | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52831060; called by muse, mutect2, varscan2
- DHRSX | c.541G>A p.V181I | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs149133886, COSV58130209; called by muse, mutect2
- DNMT1 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 23/70 reads (33%) | catalogued as COSV61580048; called by muse, mutect2, varscan2
- EIF2AK1 | c.1799A>C p.Q600P | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV52240259; called by muse, mutect2, varscan2
- FGL2 | c.399A>C p.L133F | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.823); catalogued as rs767168412, COSV50382230; called by muse, mutect2, varscan2
- GK5 | c.667T>C p.F223L | Missense Mutation (SNP) | VAF 37/113 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.53); catalogued as COSV67485903; called by muse, mutect2, varscan2
- GNL2 | c.608C>G p.S203C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66080706; called by muse, mutect2, varscan2
- GPR156 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 84/291 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1358985697, COSV59938545; called by muse, mutect2, varscan2
- GRIK3 | c.2401C>T p.R801W | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1232964890, COSV66140837; called by muse, mutect2, varscan2
- H3C11 | c.382G>C p.A128P | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58899435; called by muse, mutect2, varscan2
- HMX3 | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV63501746; called by muse, varscan2
- IMMT | c.796G>T p.A266S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.89); PolyPhen benign (0.015); catalogued as rs1290565238, COSV54487468; called by muse, mutect2, varscan2
- JPH1 | c.1070A>G p.D357G | Missense Mutation (SNP) | VAF 56/176 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV60611602; called by muse, mutect2, varscan2
- KCNG1 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs1445698303, COSV65368140; called by mutect2, varscan2
- LRRC1 | c.640C>T p.Q214* | Nonsense Mutation (SNP) | VAF 4/23 reads (17%) | catalogued as COSV100906349; called by muse, mutect2
- MLH3 | c.3280+1G>T p.X1094_splice | Splice Site (SNP) | VAF 17/55 reads (31%) | catalogued as COSV53155881; called by muse, mutect2, varscan2
- NUP54 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53575976; called by muse, mutect2
- OR52I2 | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV57045253; called by muse, mutect2, varscan2
- PCDHB3 | c.617C>T p.P206L | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.3); catalogued as rs1554272241, COSV50579426; called by muse, mutect2, varscan2
- PKD1 | c.9961G>A p.D3321N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs948156316, COSV99237985; called by muse, mutect2
- PRKACB | c.881C>A p.T294N | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65763250; called by muse, mutect2, varscan2
- RASEF | c.1888C>A p.L630I | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as COSV64586292, COSV64587377, COSV64588887; called by muse, mutect2, varscan2
- RBM10 | c.2467G>T p.E823* | Nonsense Mutation (SNP) | VAF 45/68 reads (66%) | catalogued as COSV61309624; called by muse, mutect2, varscan2
- RGS7BP | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1433978701, COSV61833341; called by muse, mutect2, varscan2
- RNF8 | c.631G>C p.E211Q | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.012); catalogued as COSV57721520; called by muse, mutect2
- SLC25A13 | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV55708517; called by muse, mutect2, varscan2
- SLC6A19 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs961526802, COSV57249361; called by muse, mutect2, varscan2
- SLC9A4 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 125/353 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.058); catalogued as rs768446992, COSV54834643; called by muse, mutect2, varscan2
- SOX9 | c.421A>G p.K141E | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.396); catalogued as COSV55424881; called by muse, mutect2
- SP140 | c.1954C>T p.R652* | Nonsense Mutation (SNP) | VAF 27/59 reads (46%) | catalogued as COSV59450818; called by muse, mutect2, varscan2
- SRP72 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV61378080; called by muse, mutect2, varscan2
- TMTC2 | c.1031A>G p.N344S | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV58271402; called by muse, mutect2, varscan2
- TRMT10C | c.403T>G p.Y135D | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV59306049; called by muse, mutect2, varscan2
- VPREB1 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.028); catalogued as COSV56425820; called by muse, mutect2, varscan2
- ZIC1 | c.535G>A p.G179S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.015); catalogued as COSV51554219, COSV51559123; called by muse, mutect2, varscan2
- ZNF492 | c.571C>A p.H191N | Missense Mutation (SNP) | VAF 116/310 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV71762028, COSV71762407; called by muse, mutect2, varscan2
- RCC2 | c.801_803del p.M267del | In Frame Del (DEL) | VAF 68/224 reads (30%) | called by mutect2, pindel, varscan2
- SENP5 | c.2063del p.N688Ifs*39 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- SOX9 | c.179dup p.K61Efs*191 | Frame Shift Ins (INS) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- BTBD3 | c.1356C>T p.P452= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as rs771415419, COSV54779644; called by muse, mutect2, varscan2
- CMYA5 | c.5961G>A p.L1987= | Silent (SNP) | VAF 20/182 reads (11%) | catalogued as COSV101484023; called by muse, mutect2, varscan2
- DNAH9 | c.3372G>A p.A1124= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs146993575; called by muse, mutect2, varscan2
- EDC4 | c.1803T>G p.P601= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV62766301; called by muse, mutect2
- EPHA7 | c.378C>T p.Y126= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV65169526; called by muse, mutect2, varscan2
- EPRS1 | c.810G>A p.S270= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as rs573093014, COSV100859302, COSV65099426; called by muse, mutect2, varscan2
- FAM50B | c.27C>T p.R9= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV66655261; called by muse, mutect2, varscan2
- IGKV1D-17 | c.258C>A p.G86= | Silent (SNP) | VAF 42/167 reads (25%) | called by muse, varscan2
- NFKBID | c.495C>T p.N165= (on ENST00000396901; = p.N317= on NM_032721.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV61729019; called by muse, mutect2, varscan2
- OR1K1 | c.372C>T p.Y124= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs761878301, COSV52956645; called by muse, mutect2, varscan2
- POR | c.1797C>T p.S599= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV58694201; called by muse, mutect2, varscan2
- SIN3B | c.3441C>T p.P1147= | Silent (SNP) | VAF 10/19 reads (53%) | catalogued as rs372556106; called by muse, mutect2, varscan2
- SMG1 | c.8664C>T p.D2888= | Silent (SNP) | VAF 33/138 reads (24%) | catalogued as rs755001924, COSV67171961; called by muse, mutect2, varscan2
- WSCD1 | c.1557C>T p.C519= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as rs758954465, COSV58495984; called by muse, mutect2, varscan2
- ZBTB11 | c.966C>T p.G322= | Silent (SNP) | VAF 63/185 reads (34%) | catalogued as rs376263121; called by muse, mutect2, varscan2
- ZDHHC15 | c.981C>A p.G327= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as COSV64902125; called by muse, mutect2, varscan2
- ZNF208 | c.3021C>A p.G1007= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs1386236173, COSV68107377; called by muse, mutect2, varscan2
- ZNF418 | c.714C>A p.S238= | Silent (SNP) | VAF 24/82 reads (29%) | catalogued as COSV68675949; called by muse, mutect2, varscan2
- NOP56 | c.1281+69G>A | Intron (SNP) | VAF 3/15 reads (20%) | catalogued as COSV100250074, COSV61390914; called by muse, mutect2
